Gene-level copy-number profile of tumor specimen TCGA-2G-AAFW-01A from TCGA case TCGA-2G-AAFW, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 34.1 years (12,464 days).
Specimen TCGA-2G-AAFW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cb8eef26-77e2-4af7-a294-3c2623685c78.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAFW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/e5235be1-918d-4235-b6f1-684bb58fcb15

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,934; copy number 1: 1,019; copy number 2: 24,348; copy number 3: 17,749; copy number 4: 5,953; copy number 5: 7,072; copy number 7: 4; copy number 8: 695; copy number 9: 97; copy number 10: 39.

Homozygous deletions (total copy number 0; autosomes only): 1,934 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:97,184,093–98,143,476, 6 genes: STPG2, AC034154.1, STPG2-AS1, CRYZP2, RPL5P12, DUTP8.
- chr11:58,834,065–135,075,908, 1,925 genes (broad region; genes not listed).
- chr18:45,034–73,545, 3 genes: AP001005.1, TUBB8B, AP001005.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,907 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:56,049,073–59,630,324, 53 genes, copy number 5: CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1.
- chr7:4,511,959–66,995,587, 1,133 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:72,558,744–137,182,107, 1,132 genes, copy number 5 (within-gene range 4–7) (broad region; genes not listed).
- chr7:137,164,043–159,233,377, 540 genes, copy number 5 (broad region; genes not listed).
- chr12:12,310–112,509,918, 2,437 genes, copy number 5–10 (broad region; genes not listed).
- chr14:18,333,726–102,933,596, 1,946 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr14:102,933,574–102,937,177, 1 gene, copy number 5 (within-gene range 2–5): AL117209.1.
- chr21:13,038,160–44,818,779, 655 genes, copy number 5 (broad region; genes not listed).
- chr21:46,324,141–46,691,226, 10 genes, copy number 5 (within-gene range 4–5): PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 507. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
